Somatic mutation profile of tumor specimen TCGA-A3-3319-01A (aliquot TCGA-A3-3319-01A-01W-0886-08) from TCGA case TCGA-A3-3319, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 70.4 years (25,699 days).
Specimen TCGA-A3-3319-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d2f312d3-9dcc-45bb-9f1b-0bfb8a515365.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A3-3319-11A (Solid Tissue Normal), aliquot TCGA-A3-3319-11A-01D-0966-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f84df3cc-e9d6-44c5-99de-8744d4ebb38e

The open-access MAF lists 100 somatic variants for this specimen: 71 protein-altering or splice-affecting, 19 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 56, Silent 19, Intron 6, Frame Shift Ins 6, Frame Shift Del 4, Nonsense Mutation 3, 3'Flank 2, In Frame Del 1, 3'UTR 1, RNA 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALLC | c.248C>T p.T83M | Missense Mutation (SNP) | VAF 102/360 reads (28%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.458); catalogued as rs755429246, COSV52994164, COSV99378331; called by muse, mutect2, varscan2
- ARHGAP24 | c.680A>C p.K227T (on ENST00000395184 / NM_001025616.3; = p.K134T on NM_031305.3) | Missense Mutation (SNP) | VAF 16/300 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as rs1467633305; called by muse, mutect2
- ATP7B | c.3181G>A p.G1061R | Missense Mutation (SNP) | VAF 26/127 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1349853812; called by muse, mutect2, varscan2
- B3GLCT | c.1462C>A p.Q488K | Missense Mutation (SNP) | VAF 37/217 reads (17%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.007); catalogued as rs1399744680; called by muse, mutect2, varscan2
- BRINP2 | c.1609C>T p.R537W | Missense Mutation (SNP) | VAF 46/126 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1196713538, COSV64180002; called by muse, mutect2, varscan2
- DNAH10 | c.1538G>A p.R513Q (on ENST00000409039; = p.R452Q on NM_207437.3) | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.537); catalogued as rs1355478360, COSV68999131; called by muse, mutect2
- ELMO1 | c.773G>C p.R258T | Missense Mutation (SNP) | VAF 335/650 reads (52%) | SIFT deleterious (0.02); PolyPhen benign (0.278); catalogued as COSV60305261; called by muse, mutect2, varscan2
- HSPG2 | c.1810G>A p.G604S | Missense Mutation (SNP) | VAF 51/190 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs764094896, COSV65978205; called by muse, mutect2, varscan2
- ITGA3 | c.226dup p.R76Pfs*27 | Frame Shift Ins (INS) | VAF 4/18 reads (22%) | catalogued as rs752236693; called by pindel, varscan2
- LARGE1 | c.1522G>A p.A508T | Missense Mutation (SNP) | VAF 61/240 reads (25%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.663); catalogued as rs770911031; called by mutect2, varscan2
- LRRC42 | c.898A>G p.N300D | Missense Mutation (SNP) | VAF 25/73 reads (34%) | SIFT tolerated (0.65); PolyPhen benign (0.115); catalogued as rs1226349388; called by muse, mutect2, varscan2
- MFSD13A | c.827A>G p.Q276R | Missense Mutation (SNP) | VAF 35/157 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53266623; called by muse, mutect2, varscan2
- MYO18A | c.248C>T p.S83F | Missense Mutation (SNP) | VAF 16/142 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.325); catalogued as rs1000787150; called by muse, varscan2
- NDST2 | c.1922A>G p.E641G | Missense Mutation (SNP) | VAF 38/196 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV104401641; called by muse, mutect2, varscan2
- PNPLA5 | c.318dup p.D107Rfs*19 | Frame Shift Ins (INS) | VAF 4/32 reads (13%) | catalogued as rs747771692; called by pindel, varscan2
- PREX1 | c.3016G>C p.D1006H | Missense Mutation (SNP) | VAF 21/153 reads (14%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.969); catalogued as rs757101993; called by muse, mutect2, varscan2
- SLC5A11 | c.26A>G p.Q9R | Missense Mutation (SNP) | VAF 23/122 reads (19%) | SIFT tolerated (0.49); PolyPhen benign (0.01); catalogued as rs758887512; called by muse, mutect2, varscan2
- SZT2 | c.31G>A p.E11K | Missense Mutation (SNP) | VAF 49/203 reads (24%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.52); catalogued as COSV60290698; called by muse, mutect2, varscan2
- TARS2 | c.4G>A p.A2T | Missense Mutation (SNP) | VAF 79/270 reads (29%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.015); catalogued as rs756811374; called by muse, mutect2, varscan2
- TFE3 | c.1445dup p.P483Tfs*138 | Frame Shift Ins (INS) | VAF 30/223 reads (13%) | catalogued as rs782753958; called by mutect2, varscan2
- ZNF175 | c.77C>T p.S26L | Missense Mutation (SNP) | VAF 101/279 reads (36%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs941405880; called by muse, mutect2, varscan2
- AC092143.1 | c.1703C>T p.T568I | Missense Mutation (SNP) | VAF 11/75 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.945); called by mutect2, varscan2
- ACO1 | c.1898T>A p.L633Q | Missense Mutation (SNP) | VAF 41/135 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.159); called by muse, mutect2, varscan2
- BPTF | c.4332G>T p.Q1444H | Missense Mutation (SNP) | VAF 16/188 reads (9%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); called by muse, mutect2
- C1S | c.998G>A p.G333D | Missense Mutation (SNP) | VAF 110/485 reads (23%) | SIFT tolerated (0.56); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CCDC141 | c.2636G>A p.S879N | Missense Mutation (SNP) | VAF 73/2267 reads (3%) | SIFT tolerated (0.15); PolyPhen benign (0.073); called by muse, mutect2
- CCDC24 | c.734T>A p.L245H | Missense Mutation (SNP) | VAF 38/204 reads (19%) | SIFT tolerated (0.16); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- CNTNAP1 | c.3190del p.R1064Gfs*70 | Frame Shift Del (DEL) | VAF 13/113 reads (12%) | called by mutect2, pindel, varscan2
- DGCR8 | c.1705+1G>C p.X569_splice | Splice Site (SNP) | VAF 51/246 reads (21%) | called by muse, mutect2, varscan2
- DIO2 | c.781A>T p.N261Y | Missense Mutation (SNP) | VAF 11/21 reads (52%) | SIFT tolerated (1); PolyPhen possibly damaging (0.883); called by muse, mutect2, varscan2
- DMD | c.7600G>C p.A2534P | Missense Mutation (SNP) | VAF 24/190 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- DNAJB4 | c.132A>T p.K44N | Missense Mutation (SNP) | VAF 25/80 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- ERC1 | c.2315A>G p.K772R (on ENST00000360905 / NM_178040.4; = p.K744R on NM_178039.4) | Missense Mutation (SNP) | VAF 47/420 reads (11%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- GAK | c.2240_2241insCCTGAAAGAGGCTGTA p.K748Lfs*6 | Frame Shift Ins (INS) | VAF 47/93 reads (51%) | called by mutect2, varscan2*
- GARRE1 | c.122T>C p.L41P | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GPRC5C | c.1367A>G p.E456G (on ENST00000652232; = p.E411G on NM_018653.4) | Missense Mutation (SNP) | VAF 70/188 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- HEPH | c.209G>T p.G70V (on ENST00000343002; = p.G124V on NM_138737.5) | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KLF12 | c.505C>A p.P169T | Missense Mutation (SNP) | VAF 17/98 reads (17%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- KLHL4 | c.1756del p.S586Qfs*37 | Frame Shift Del (DEL) | VAF 69/138 reads (50%) | called by mutect2, pindel, varscan2
- KLK6 | c.313C>T p.Q105* | Nonsense Mutation (SNP) | VAF 10/56 reads (18%) | called by muse, mutect2, varscan2
- LRRTM1 | c.4G>C p.D2H | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- LYG1 | c.327G>C p.M109I | Missense Mutation (SNP) | VAF 57/486 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0); called by muse, mutect2, varscan2
- MEI1 | c.2677C>A p.L893M | Missense Mutation (SNP) | VAF 75/232 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.177); called by muse, mutect2, varscan2
- MEX3B | c.630G>T p.M210I | Missense Mutation (SNP) | VAF 146/262 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.754); called by muse, varscan2
- MICAL3 | c.2203G>T p.E735* | Nonsense Mutation (SNP) | VAF 79/445 reads (18%) | called by muse, mutect2, varscan2
- MOCS3 | c.1037A>T p.D346V | Missense Mutation (SNP) | VAF 166/505 reads (33%) | SIFT deleterious (0.05); PolyPhen benign (0.248); called by muse, mutect2, varscan2
- MPND | c.587A>G p.D196G | Missense Mutation (SNP) | VAF 36/98 reads (37%) | SIFT tolerated (0.26); PolyPhen benign (0); called by muse, mutect2, varscan2
- MYO15A | c.9104C>T p.S3035F | Missense Mutation (SNP) | VAF 22/113 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.471); called by muse, mutect2, varscan2
- NFASC | c.1382C>T p.T461I (on ENST00000339876 / NM_001378329.1; = p.T472I on NM_015090.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/154 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- NR3C2 | c.1822G>T p.D608Y | Missense Mutation (SNP) | VAF 15/324 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PCCB | c.1303T>C p.Y435H | Missense Mutation (SNP) | VAF 268/341 reads (79%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PCDH7 | c.1579G>T p.D527Y | Missense Mutation (SNP) | VAF 5/53 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PPP6R3 | c.1651A>G p.M551V (on ENST00000393800 / NM_001352375.2; = p.M471V on NM_018312.5) | Missense Mutation (SNP) | VAF 86/418 reads (21%) | SIFT tolerated (0.26); PolyPhen benign (0.074); called by muse, varscan2
- PTPRD | c.4096C>T p.P1366S | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.203); called by muse, varscan2
- RAD54L2 | c.938T>A p.L313* | Nonsense Mutation (SNP) | VAF 57/153 reads (37%) | called by muse, mutect2, varscan2
- RESF1 | c.3890T>G p.L1297W | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.486); called by muse, mutect2, varscan2
- RIOK2 | c.1012G>A p.D338N | Missense Mutation (SNP) | VAF 116/442 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SGCA | c.25_26insAA p.P9Qfs*39 | Frame Shift Ins (INS) | VAF 73/383 reads (19%) | called by mutect2, pindel, varscan2
- SLC15A4 | c.1383dup p.G462Wfs*65 | Frame Shift Ins (INS) | VAF 26/185 reads (14%) | called by mutect2, pindel, varscan2
- SMARCA4 | c.3691G>A p.A1231T | Missense Mutation (SNP) | VAF 52/291 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); called by muse, mutect2, varscan2
- SMC1B | c.3456T>G p.D1152E | Missense Mutation (SNP) | VAF 19/156 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); called by muse, mutect2, varscan2
- SPAG1 | c.2447_2448del p.L816Qfs*6 | Frame Shift Del (DEL) | VAF 36/106 reads (34%) | called by pindel, varscan2
- SPATA31D1 | c.2253C>G p.S751R | Missense Mutation (SNP) | VAF 15/120 reads (13%) | SIFT tolerated (0.27); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- SYNRG | c.3723del p.N1241Kfs*12 | Frame Shift Del (DEL) | VAF 33/209 reads (16%) | called by mutect2, pindel, varscan2
- TBL1XR1 | c.365G>A p.G122E | Missense Mutation (SNP) | VAF 45/90 reads (50%) | SIFT tolerated (1); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- TMEM182 | c.233C>T p.T78I | Missense Mutation (SNP) | VAF 85/369 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- TRDMT1 | c.1033C>G p.P345A | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); called by muse, mutect2, varscan2
- UBE4B | c.3580_3582del p.G1194del (on ENST00000343090 / NM_001105562.3; = p.G1065del on NM_006048.5) | In Frame Del (DEL) | VAF 22/161 reads (14%) | called by mutect2, pindel, varscan2
- UNC13B | c.2713A>T p.M905L | Missense Mutation (SNP) | VAF 33/111 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- USP15 | c.898A>C p.M300L (on ENST00000280377 / NM_001351159.2; = p.M271L on NM_006313.3 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 49/197 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- YARS1 | c.1363C>G p.L455V | Missense Mutation (SNP) | VAF 19/126 reads (15%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.797); called by muse, mutect2, varscan2
- A2ML1 | c.774G>A p.V258= | Silent (SNP) | VAF 20/582 reads (3%) | called by muse, mutect2
- ADGRV1 | c.13386G>A p.G4462= | Silent (SNP) | VAF 75/162 reads (46%) | called by muse, mutect2, varscan2
- ANK2 | c.2349T>C p.H783= | Silent (SNP) | VAF 36/91 reads (40%) | catalogued as rs1432284899; called by muse, mutect2, varscan2
- ASH1L | c.2445C>G p.V815= | Silent (SNP) | VAF 74/270 reads (27%) | catalogued as rs1393051424; called by muse, varscan2
- CC2D2A | c.2541C>T p.D847= | Silent (SNP) | VAF 19/133 reads (14%) | catalogued as rs1212761897; called by muse, mutect2, varscan2
- CHD1 | c.2100A>G p.K700= | Silent (SNP) | VAF 193/293 reads (66%) | called by muse, mutect2, varscan2
- CNNM4 | c.2274T>G p.L758= | Silent (SNP) | VAF 9/122 reads (7%) | called by muse, mutect2
- DHX58 | c.492G>A p.L164= | Silent (SNP) | VAF 302/490 reads (62%) | catalogued as rs199844647; called by muse, mutect2, varscan2
- EVC | c.588C>T p.N196= | Silent (SNP) | VAF 28/129 reads (22%) | catalogued as rs756994584; called by muse, mutect2, varscan2
- HOPX | c.9G>T p.A3= (on ENST00000317745; = p.A21= on NM_032495.6) | Silent (SNP) | VAF 9/27 reads (33%) | called by muse, mutect2, varscan2
- LRP5 | c.3549C>G p.T1183= | Silent (SNP) | VAF 70/254 reads (28%) | called by muse, mutect2, varscan2
- MEX3A | c.663C>T p.P221= | Silent (SNP) | VAF 26/70 reads (37%) | catalogued as rs765160121; called by muse, varscan2
- MTFR1 | c.642A>G p.R214= | Silent (SNP) | VAF 33/218 reads (15%) | called by muse, mutect2, varscan2
- PCDHGC3 | c.2241G>A p.V747= | Silent (SNP) | VAF 14/164 reads (9%) | catalogued as rs1437200116; called by muse, mutect2
- PSD4 | c.1131C>A p.V377= | Silent (SNP) | VAF 66/1332 reads (5%) | called by muse, mutect2
- SEC31A | c.1053A>G p.S351= | Silent (SNP) | VAF 45/151 reads (30%) | catalogued as rs1221266124; called by muse, mutect2, varscan2
- SERPINH1 | c.765C>T p.I255= | Silent (SNP) | VAF 44/195 reads (23%) | catalogued as rs369937589; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLCO1B3 | c.1650A>G p.T550= | Silent (SNP) | VAF 50/177 reads (28%) | catalogued as rs763443499, COSV53936718; called by muse, mutect2, varscan2
- SPECC1 | c.90C>T p.S30= | Silent (SNP) | VAF 72/416 reads (17%) | catalogued as rs199639674, COSV54959759; called by muse, mutect2, varscan2
- ACSM1 | c.1197+186C>T | Intron (SNP) | VAF 390/964 reads (40%) | catalogued as rs764236242; called by muse, mutect2, varscan2
- AL590867.2 | n.427dup | RNA (INS) | VAF 7/44 reads (16%) | catalogued as rs747858319; called by mutect2, varscan2
- AP4B1 | c.*1_*2del | 3'UTR (DEL) | VAF 4/30 reads (13%) | catalogued as rs1302681844; called by mutect2, pindel, varscan2
- CNOT11 | chr2:101272947 A>G | 3'Flank (SNP) | VAF 145/455 reads (32%) | called by muse, mutect2, varscan2
- CNTROB | c.2513+54G>A | Intron (SNP) | VAF 34/326 reads (10%) | catalogued as rs758365980; called by muse, varscan2
- DNM3 | c.1689+13355C>T | Intron (SNP) | VAF 28/111 reads (25%) | called by muse, mutect2, varscan2
- OBSCN | c.5138-1798C>T | Intron (SNP) | VAF 6/25 reads (24%) | called by muse, mutect2, varscan2
- SCARB1 | c.1651+3421_1651+3422del | Intron (DEL) | VAF 85/364 reads (23%) | catalogued as rs770327774; called by mutect2, pindel, varscan2
- TP63 | c.1350-6225G>A | Intron (SNP) | VAF 20/171 reads (12%) | called by muse, mutect2, varscan2
- USP34 | chr2:61186466 C>G | 3'Flank (SNP) | VAF 47/143 reads (33%) | called by muse, mutect2, varscan2
